Surgical pathology report (de-identified scan), TCGA case TCGA-IM-A3EB, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Miami, specimen TCGA-IM-A3EB-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Name: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Gender: F
MRN: [REDACTED]
Location: [REDACTED]
Physician: [REDACTED]

Case #: [REDACTED]
Collected: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]
Copy To: [REDACTED]

Pathologic Interpretation:

A. Right hemithyroidectomy:

- Papillary thyroid carcinoma:

- Tumor size: 3.0 cm in greatest dimension.
- Tumor extent: the tumor focally extends through the thyroid gland capsule, microscopically extending into the surrounding skeletal muscle.
- Lymphovascular invasion: present.
- Margins of resection are free of tumor (but the tumor approaches the peripheral margin within 1.0 millimeter).
- AJCC Pathologic TNM Staging: pT3, pN1a, pMx.

- Other findings: Chronic lymphocytic thyroiditis.

B. Tissue at the right inferior laryngeal nerve:

- Microscopic focus of metastatic thyroid carcinoma (1/1).

Note: The tumoral focus was not present in the frozen section slide (only present in the permanent sections). A positive cytokeratin immunostain confirms the diagnosis.

C. Lateral margin at the pharyngeal constrictor muscle:

- Skeletal muscle, free of tumor.

D. Left hemithyroidectomy:

- Chronic lymphocytic thyroiditis.

E. Pre-laryngeal lymph nodes:

- Fragments of thyroid tissue with chronic lymphocytic thyroiditis.
- Micrometastasis of thyroid carcinoma in the subcapsular sinus of one out of two lymph nodes, (1/2).
- Salivary gland tissue with no pathologic changes.

F. Right paratracheal lymph node dissection:

- Metastatic thyroid carcinoma in one lymph node, out of nine nodes dissected (1/9).
- One parathyroid gland.

Tumor Summary:

Specimen Type: Total thyroidectomy

Tumor Site: Right lobe

Tumor Focality: Unifocal

Tumor Size (largest nodule):

Greatest dimension: 3 cm

Additional dimensions: 2 x 2 cm

Histologic Type: Papillary carcinoma

Pathologic Staging:

Primary Tumor:

- pT3: Tumor with minimal extrathyroid extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

Regional Lymph Nodes:

- pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal / Delphian) lymph nodes

-Specify: Number examined: 12

Number involved: 3

ICD-O-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

10/26/11

[page 2 of 3]
[REDACTED]

Distant Metastasis:

- pMX: Cannot be assessed

Margins: Uninvolved by carcinoma

-Distance of invasive carcinoma to closest margin: less than 1 mm

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Present

Additional Pathologic Findings:

- Thyroiditis

Pathologic Staging: pT3, pN1a, pMX

NOTE: Some immunohistochemical antibodies are antibody specific reagents (ASRs) validated by our laboratory. These ASRs are clinically useful indicators that do not require FDA approval. These clones are used: ID5=ER, PgR 636=PR, A433=HER2, H-11=EGFR. All immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by brown chromogen. Results are read by a pathologist as positive or negative.

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

[REDACTED]

Electronically Signed Out By

[REDACTED]

Intraoperative Consultation

B. Tissue at the right inferior laryngeal nerve, FS: Lymph node and a vessel, no tumor seen.

C. Lateral margin at the pharyngeal constrictor muscle, FS: Skeletal muscle, free of tumor.

[REDACTED]

Clinical History:

None Provided

Operation Performed

Thyroidectomy

Pre Operative Diagnosis:

Thyroid cancer

Specimen(s) Received:

- A: Right thyroid suture marks superior
- B: Tissue at the right inferior laryngeal nerve, FS
- C: Lateral margin at the pharyngeal constrictor muscle, FS
- D: Left thyroid lobe suture marks superior aspect
- E: Prelaryngeal lymph nodes
- F: Right paratracheal lymph node dissection

Gross Description:

- A. Received fresh is the right lobe of the thyroid which measures 7.0 x 3.7 x 2.0 cm and weighs 26 grams. The specimen is oriented with a suture at the right superior pole. Resection margin is inked black. Sections reveal a well circumscribed light tan nodular lesion which measures 3.0 x 2.0 x 2.0 cm. The cut surface shows papillary appearance. The lesion seems to be confined to the thyroid parenchyma. The remainder of the thyroid shows an ordered well circumscribed light tan nodular lesion which measures 0.3 cm in greatest dimension, located at 1.7 cm from the main nodular lesion. This lesion is also at 1.5 cm from the medial resection margin and at 0.7 cm from the anterior aspect of the specimen. The

[page 3 of 3]
remainder of the thyroid parenchyma is brown, firm in consistency with irregular appearance. Sections submitted as follows:

- 1 Upper pole resection margin with lesions
- 2 Anterior aspect of the specimen with lesion
- 3 Posterior aspect of the specimen with lesions
- 4 Lesion and normal thyroid
- 5 Smaller nodular lesion
- 6 Normal parenchyma from the remainder of the thyroid

- B. Received fresh is an irregularly shaped light tan soft tissue fragment which measures 0.6 cm in greatest dimension. Submitted in toto in one cassette for frozen.
- C. Received fresh is an irregular light tan soft tissue fragment which measures 0.6 cm in greatest dimension. Submitted in toto in one cassette for frozen.
- D. Received in formalin is a left lobe of the thyroid which measures 6.0 x 3.0 x 2.0 cm and weighs 12 grams. The specimen is oriented with one suture at the superior pole. The resection margin is inked black. Sections reveal light tan multinodular appearance, mainly at the posterior aspect of the specimen. The largest nodular area measures 1.0 cm in greatest dimension. Sections submitted as follows:
- 1 Perpendicular resection margin at the isthmus
- 2 Perpendicular resection margin at the upper pole
- 3 Posterior aspect of the specimen with nodular lesion
- 4-6 From the remainder of the specimen with nodular lesions
- E. Received in formalin is a single irregularly shaped light tan soft tissue fragment which measures 2.0 x 1.5 x 1.0 cm. Sections reveal four lymph nodes, ranging in size from 0.9 x 0.7 x 0.5 cm to 0.4 cm in greatest dimension. Sections submitted as follows:
- 1&2 One lymph node per cassette, bisected
- 3 Two lymph nodes submitted in toto
- F. Received in formalin is an irregularly shaped light soft tissue fragment which measures 3.0 x 2.0 x 1.0 cm. Sections reveal twelve lymph nodes, ranging in size from 0.7 x 0.5 x 0.3 cm to 0.4 cm in greatest dimension. Sections submitted as follows:
- 1&2 One lymph node per cassette bisected
- 3&4 Five lymph nodes per cassette, submitted in toto

Source: NCI Genomic Data Commons file 196cb99c-7c11-4112-a854-2e4ead93920f (TCGA-IM-A3EB.22185BE8-EB63-43CE-AC8C-93BBD20A8570.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).